Somatic mutation profile of tumor specimen TCGA-3K-AAZ8-01A (aliquot TCGA-3K-AAZ8-01A-12D-A38X-10) from TCGA case TCGA-3K-AAZ8, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIB; Tumor grade: G1; Age at diagnosis: 65.8 years (24,046 days).
Specimen TCGA-3K-AAZ8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df52547e-b9a9-4e94-82d2-46fac59d03f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3K-AAZ8-10A (Blood Derived Normal), aliquot TCGA-3K-AAZ8-10A-01D-A38X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca6c0cdc-6684-47bd-be80-7c2a570499bc

The open-access MAF lists 149 somatic variants for this specimen: 111 protein-altering or splice-affecting, 32 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 32, Nonsense Mutation 6, Frame Shift Del 4, RNA 4, Splice Site 3, In Frame Del 2, Intron 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 57/117 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: other / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1876A>C p.N626H | Missense Mutation (SNP) | VAF 13/114 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59206442, COSV59212920, COSV59229378; called by muse, mutect2, varscan2
- ABCA4 | c.1864A>C p.S622R | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV100933187; called by muse, mutect2
- ABCC1 | c.2195T>A p.L732Q | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as COSV100580093; called by muse, mutect2, varscan2
- ABCC9 | c.1979G>A p.R660Q | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as rs150255709; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACER3 | c.704G>C p.S235T | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.093); catalogued as COSV99568680; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1291C>T p.R431* | Nonsense Mutation (SNP) | VAF 53/149 reads (36%) | catalogued as rs1417501235, COSV100416772; called by muse, mutect2, varscan2
- AKAP1 | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.122); catalogued as rs538528140, COSV100028190; called by muse, mutect2
- AL592490.1 | c.2456G>A p.R819H | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs1047769718, COSV101308259; called by muse, mutect2, varscan2
- ANGPTL2 | c.1166A>C p.E389A | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99402273; called by muse, mutect2
- ARID2 | c.1109T>G p.L370* | Nonsense Mutation (SNP) | VAF 50/102 reads (49%) | catalogued as COSV100536711, COSV57605303; called by muse, mutect2, varscan2
- ARMC3 | c.1570G>C p.D524H | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV99958647; called by muse, mutect2, varscan2
- ATP6V1E2 | c.309C>A p.S103R | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.033); catalogued as COSV100120791; called by muse, mutect2, varscan2
- AXDND1 | c.2083C>A p.Q695K | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.066); catalogued as COSV100858564; called by muse, mutect2, varscan2
- BMP7 | c.1184G>T p.C395F | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101216172; called by muse, mutect2
- BPIFC | c.700A>T p.I234F | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV100301187; called by muse, mutect2, varscan2
- BTBD3 | c.297G>A p.W99* | Nonsense Mutation (SNP) | VAF 82/173 reads (47%) | catalogued as COSV99656044; called by muse, mutect2, varscan2
- CATSPERE | c.347C>T p.T116I | Missense Mutation (SNP) | VAF 60/401 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.534); catalogued as COSV100835294; called by muse, mutect2, varscan2
- CD22 | c.1010A>T p.Q337L | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.072); catalogued as COSV99323593; called by muse, mutect2, varscan2
- CDC37 | c.48A>C p.E16D | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99705852; called by muse, mutect2, varscan2
- CDH17 | c.1757G>A p.G586D | Missense Mutation (SNP) | VAF 76/105 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as rs189236130, COSV50329109, COSV50347397; called by muse, mutect2, varscan2
- CDK13 | c.3724A>C p.I1242L | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99475911; called by muse, mutect2, varscan2
- CFAP65 | c.4106G>A p.R1369Q | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as rs564721573, COSV100445669; called by muse, mutect2, varscan2
- CHRNA5 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs202057419, COSV55137286, COSV55140132; called by muse, mutect2, varscan2
- CNBD1 | c.810G>T p.M270I | Missense Mutation (SNP) | VAF 8/218 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV73074100; called by muse, mutect2
- CNNM1 | c.1780T>C p.F594L | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV100763949; called by muse, mutect2, varscan2
- CRISPLD1 | c.961A>G p.K321E | Missense Mutation (SNP) | VAF 47/286 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV100082315; called by muse, mutect2, varscan2
- CSMD2 | c.8080A>T p.R2694W | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99593482; called by muse, mutect2, varscan2
- CTC1 | c.419G>T p.G140V | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100236677, COSV59854195; called by muse, mutect2, varscan2
- CXorf38 | c.188G>A p.G63D | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV100010495; called by muse, mutect2, varscan2
- CYLD | c.1723A>C p.T575P | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100282661, COSV100282750; called by muse, mutect2, varscan2
- CYP2C9 | c.723A>C p.K241N | Missense Mutation (SNP) | VAF 17/454 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.152); catalogued as COSV99583030; called by muse, mutect2
- DCHS1 | c.9784G>C p.A3262P | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV100197647; called by muse, mutect2, varscan2
- DSCAML1 | c.2368G>A p.G790R (on ENST00000321322; = p.G730R on NM_020693.4) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs778578406, COSV100356752, COSV58386008; called by muse, varscan2
- E2F1 | c.872G>T p.G291V | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99865037; called by muse, mutect2, varscan2
- EID3 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100723541; called by muse, mutect2, varscan2
- EMC1 | c.386A>T p.Q129L | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV100617504; called by muse, mutect2, varscan2
- ENTHD1 | c.1493C>G p.S498C | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1031933339, COSV100288994; called by muse, mutect2, varscan2
- EXO1 | c.1246A>G p.I416V | Missense Mutation (SNP) | VAF 32/196 reads (16%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs1318996674, COSV100800077; called by muse, mutect2, varscan2
- FASTK | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.382); catalogued as rs756789798, COSV52540552, COSV52541544; called by muse, mutect2
- FBN2 | c.4274G>T p.C1425F | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM090536, CM093743, COSV52513406, COSV99329695; called by muse, mutect2, varscan2
- FBXO9 | c.13A>G p.I5V | Missense Mutation (SNP) | VAF 84/146 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99762594; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1771G>A p.V591I | Missense Mutation (SNP) | VAF 74/295 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.84); catalogued as rs1450728300, COSV100437525; called by muse, varscan2
- FRMD1 | c.913C>A p.Q305K | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99350025; called by muse, mutect2, varscan2
- GADD45G | c.353A>C p.H118P | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV99378650; called by muse, mutect2, varscan2
- GPT2 | c.1093G>T p.G365C | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV100413013; called by muse, mutect2, varscan2
- GRM2 | c.1810G>T p.E604* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as COSV99623055; called by muse, mutect2, varscan2
- HAX1 | c.40C>A p.P14T | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV55167516, COSV99671945; called by muse, mutect2, varscan2
- IL23R | c.461T>A p.I154K | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV100724866; called by muse, mutect2, varscan2
- KIAA2026 | c.4339A>G p.K1447E | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs1414259473, COSV101199164; called by muse, mutect2, varscan2
- KIF15 | c.1190G>T p.G397V | Missense Mutation (SNP) | VAF 79/307 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV100393128; called by muse, mutect2
- KMT2D | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV99984657; called by muse, mutect2, varscan2
- KNTC1 | c.2165G>C p.R722P | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV100338641, COSV61078993; called by muse, mutect2, varscan2
- LCA5 | c.601T>C p.F201L | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0.013); catalogued as COSV100878311, COSV100878347; called by muse, mutect2
- LGSN | c.284T>G p.L95R | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101040632; called by muse, mutect2, varscan2
- LRP1 | c.3026C>A p.A1009D | Missense Mutation (SNP) | VAF 41/63 reads (65%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV99676741; called by muse, mutect2, varscan2
- MAN2A1 | c.725A>G p.Q242R | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV99811634; called by muse, mutect2, varscan2
- MAPK9 | c.997-1G>A p.X333_splice | Splice Site (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100558514; called by muse, mutect2, varscan2
- METTL5 | c.497A>G p.Q166R | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV99641837; called by muse, mutect2, varscan2
- MFSD11 | c.188A>G p.N63S | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); catalogued as COSV100334181; called by muse, mutect2, varscan2
- MLH3 | c.2152C>G p.P718A | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as COSV99470565; called by muse, mutect2, varscan2
- MPST | c.629A>G p.N210S (on ENST00000341116 / NM_001369904.2; = p.N230S on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.244); catalogued as COSV100353419; called by muse, mutect2, varscan2
- MPV17L | c.461G>A p.G154E (on ENST00000396385 / NM_001128423.2; = p.W130* on NM_173803.4) | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99806279; called by muse, mutect2, varscan2
- MYO3B | c.1185+1G>A p.X395_splice | Splice Site (SNP) | VAF 7/81 reads (9%) | catalogued as COSV100511244; called by muse, mutect2
- NEDD4L | c.113T>A p.F38Y | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV99896099; called by muse, mutect2, varscan2
- NLRP3 | c.2284A>G p.T762A | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1366316812, COSV100276457; called by muse, mutect2, varscan2
- NMNAT1 | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101020436; called by muse, mutect2, varscan2
- OMA1 | c.1315C>T p.H439Y | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100678333; called by muse, mutect2, varscan2
- OR10K2 | c.284T>A p.L95Q | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.1); catalogued as COSV100149608; called by muse, mutect2, varscan2
- P2RX7 | c.1436G>A p.C479Y | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99947675; called by muse, mutect2, varscan2
- PCDHB16 | c.1338T>A p.D446E | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99502569; called by muse, mutect2, varscan2
- PDZD4 | c.2273G>A p.R758Q | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as COSV99381568; called by muse, mutect2, varscan2
- PRDM16 | c.2536C>T p.R846W | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs752922142, COSV99578135; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKCH | c.1181A>T p.D394V | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1446837577, COSV100273628; called by muse, mutect2, varscan2
- PTPRU | c.1348A>T p.I450F | Missense Mutation (SNP) | VAF 137/285 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV100113450; called by muse, mutect2, varscan2
- PYGO2 | c.691G>A p.G231S | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV100868976; called by muse, mutect2
- RAB14 | c.593A>G p.Q198R | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV99443302; called by muse, mutect2, varscan2
- REG1A | c.335A>G p.H112R | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.86); catalogued as COSV99286937; called by muse, mutect2, varscan2
- RIPOR2 | c.115A>T p.I39F | Missense Mutation (SNP) | VAF 69/118 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV99429833; called by muse, mutect2, varscan2
- ROM1 | c.710C>G p.P237R | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.944); catalogued as rs374111556; called by muse, mutect2, varscan2
- RTKN2 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as COSV100189557; called by muse, mutect2, varscan2
- SCYL1 | c.793G>A p.G265S | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.205); catalogued as COSV99534444; called by muse, mutect2, varscan2
- SERPINB13 | c.383A>G p.Y128C | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778055711, COSV54030049; called by muse, mutect2, varscan2
- SFTPB | c.1141C>T p.L381F | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100667268; called by muse, mutect2, varscan2
- SFTPB | c.1140C>A p.D380E | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as rs1350677115, COSV100667272; called by muse, mutect2, varscan2
- SLC44A5 | c.161T>C p.V54A | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV100902378; called by muse, varscan2
- SPINT1 | c.343G>C p.A115P | Missense Mutation (SNP) | VAF 52/94 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100689172; called by muse, mutect2, varscan2
- STAR | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV99379142; called by muse, mutect2, varscan2
- STX8 | c.212+1G>A p.X71_splice | Splice Site (SNP) | VAF 32/70 reads (46%) | catalogued as COSV100111369; called by muse, mutect2, varscan2
- SUPT5H | c.1574C>T p.A525V | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100782127; called by muse, mutect2, varscan2
- SYCP2 | c.2719G>A p.G907S | Missense Mutation (SNP) | VAF 65/290 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as rs1217184091, COSV100698388; called by muse, mutect2, varscan2
- TEX14 | c.2308G>T p.E770* (on ENST00000240361 / NM_001201457.2; = p.E764* on NM_031272.5) | Nonsense Mutation (SNP) | VAF 66/160 reads (41%) | catalogued as COSV53615627, COSV99543108; called by muse, mutect2, varscan2
- TGS1 | c.1622A>G p.H541R | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs914201519, COSV99485605; called by muse, mutect2, varscan2
- TMEM131L | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99547917; called by muse, mutect2, varscan2
- TNFSF18 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 89/142 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99514103; called by muse, mutect2, varscan2
- TSHZ3 | c.3149T>C p.F1050S | Missense Mutation (SNP) | VAF 71/172 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53679664; called by muse, mutect2, varscan2
- TTN | c.39803T>A p.L13268H (on ENST00000591111; = p.L5844H on NM_003319.4) | Missense Mutation (SNP) | VAF 17/163 reads (10%) | PolyPhen probably damaging (0.999); catalogued as COSV100623612, COSV59967055; called by muse, mutect2, varscan2
- ULK2 | c.1984G>A p.A662T | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1302627302, COSV100860931; called by muse, mutect2, varscan2
- WDR64 | c.1781T>C p.L594P | Missense Mutation (SNP) | VAF 70/106 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100843955; called by muse, mutect2
- ZAP70 | c.755A>T p.E252V | Missense Mutation (SNP) | VAF 61/125 reads (49%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.528); catalogued as COSV99385838; called by muse, mutect2, varscan2
- ZC3HAV1 | c.7G>T p.D3Y | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99648931; called by muse, mutect2
- ZNF106 | c.710A>T p.Y237F | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as COSV99782991; called by muse, mutect2, varscan2
- ZNF347 | c.179T>A p.L60* | Nonsense Mutation (SNP) | VAF 57/142 reads (40%) | catalogued as COSV100498378, COSV61967860; called by muse, mutect2, varscan2
- ZNF521 | c.2171G>T p.C724F | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100831582, COSV100833015; called by muse, mutect2, varscan2
- ALB | c.922_924del p.L308del | In Frame Del (DEL) | VAF 30/120 reads (25%) | called by mutect2, pindel, varscan2
- BEST1 | c.621_632del p.Q208_L211del | In Frame Del (DEL) | VAF 8/47 reads (17%) | called by mutect2, pindel, varscan2
- CHEK1 | c.21dup p.D8Rfs*22 | Frame Shift Ins (INS) | VAF 23/149 reads (15%) | called by mutect2, pindel, varscan2
- CRYBG2 | c.1293del p.S432Afs*33 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | called by mutect2, pindel, varscan2
- DENND5B | c.358del p.Y120Mfs*52 | Frame Shift Del (DEL) | VAF 32/86 reads (37%) | called by mutect2, pindel, varscan2
- GIGYF1 | c.668del p.G223Afs*122 | Frame Shift Del (DEL) | VAF 29/65 reads (45%) | called by mutect2, pindel, varscan2
- MRGPRF | c.937del p.A313Pfs*110 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | called by mutect2, pindel, varscan2
- ARID1B | c.6510G>A p.Q2170= | Silent (SNP) | VAF 38/110 reads (35%) | catalogued as rs866784097, COSV99271024; called by muse, mutect2, varscan2
- BOD1L1 | c.8910C>T p.R2970= | Silent (SNP) | VAF 41/75 reads (55%) | catalogued as COSV99240065; called by muse, mutect2, varscan2
- CHIA | c.843T>A p.I281= (on ENST00000343320; = p.I173= on NM_021797.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as COSV100588785; called by muse, mutect2, varscan2
- CHST5 | c.642G>A p.A214= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs766247065, COSV100292091; called by muse, mutect2, varscan2
- CPAMD8 | c.5634C>T p.S1878= (on ENST00000651564; = p.S1831= on NM_015692.5) | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs1413275739, COSV99935379; called by muse, mutect2, varscan2
- DOCK8 | c.2187T>C p.V729= | Silent (SNP) | VAF 41/85 reads (48%) | catalogued as COSV101210024; called by muse, mutect2, varscan2
- FOXO1 | c.825A>G p.A275= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV101092101; called by muse, mutect2, varscan2
- GAB4 | c.1312A>C p.R438= | Silent (SNP) | VAF 51/109 reads (47%) | catalogued as COSV101272065, COSV101272066; called by muse, mutect2, varscan2
- GATAD2A | c.1401G>A p.Q467= | Silent (SNP) | VAF 52/135 reads (39%) | catalogued as COSV99390548; called by muse, mutect2, varscan2
- GNB4 | c.519T>G p.T173= | Silent (SNP) | VAF 35/228 reads (15%) | catalogued as COSV99224424; called by muse, mutect2, varscan2
- IFNG | c.69C>T p.C23= | Silent (SNP) | VAF 90/202 reads (45%) | catalogued as COSV99971240; called by muse, mutect2, varscan2
- KCNH5 | c.1875T>C p.H625= | Silent (SNP) | VAF 70/146 reads (48%) | catalogued as rs1282718979, COSV100527583; called by muse, mutect2, varscan2
- KCNH8 | c.556T>C p.L186= | Silent (SNP) | VAF 36/137 reads (26%) | catalogued as rs150723210; called by muse, mutect2, varscan2
- LENG8 | c.411A>G p.Q137= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100457962; called by muse, mutect2
- MARCHF10 | c.429G>T p.L143= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV100248458, COSV60887682; called by muse, mutect2, varscan2
- NEU3 | c.1008A>C p.A336= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs776965933, COSV99579644; called by muse, mutect2, varscan2
- OR2AG1 | c.696G>A p.E232= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as COSV100264935; called by muse, mutect2, varscan2
- OR5H2 | c.156T>C p.A52= | Silent (SNP) | VAF 47/100 reads (47%) | catalogued as COSV100788797; called by muse, mutect2, varscan2
- OR5K4 | c.202C>T p.L68= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV100721384; called by muse, mutect2, varscan2
- OR8B4 | c.531G>T p.L177= | Silent (SNP) | VAF 50/87 reads (57%) | catalogued as rs1196462007, COSV100635860; called by muse, mutect2, varscan2
- POLB | c.594C>A p.P198= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV99613324; called by muse, mutect2, varscan2
- PXDNL | c.2025T>C p.R675= | Silent (SNP) | VAF 69/100 reads (69%) | catalogued as COSV62485547; called by muse, mutect2, varscan2
- RGS7BP | c.102G>A p.E34= | Silent (SNP) | VAF 112/266 reads (42%) | catalogued as COSV100471142; called by muse, mutect2, varscan2
- SCG2 | c.1341T>C p.N447= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as COSV100544845; called by muse, mutect2, varscan2
- SEMA3F | c.2016T>C p.D672= | Silent (SNP) | VAF 36/67 reads (54%) | catalogued as COSV99137761; called by muse, mutect2, varscan2
- SRFBP1 | c.612A>T p.P204= | Silent (SNP) | VAF 80/185 reads (43%) | catalogued as COSV100232880; called by muse, mutect2, varscan2
- TNFRSF21 | c.687C>T p.I229= | Silent (SNP) | VAF 41/148 reads (28%) | catalogued as COSV99730066; called by muse, mutect2, varscan2
- TRIM11 | c.696C>T p.L232= | Silent (SNP) | VAF 44/79 reads (56%) | catalogued as rs763571305, COSV99488794; called by muse, mutect2, varscan2
- TSN | c.582C>T p.R194= | Silent (SNP) | VAF 37/79 reads (47%) | catalogued as COSV101067561; called by muse, mutect2, varscan2
- TTN | c.80946T>C p.Y26982= (on ENST00000591111; = p.Y19558= on NM_003319.4) | Silent (SNP) | VAF 52/99 reads (53%) | catalogued as COSV100623610; called by muse, mutect2, varscan2
- ZNF483 | c.1314T>C p.T438= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as COSV100493071; called by muse, mutect2, varscan2
- ZNF609 | c.2370T>C p.A790= | Silent (SNP) | VAF 42/75 reads (56%) | catalogued as rs368660859; called by muse, mutect2, varscan2
- BIRC8 | n.1244A>T | RNA (SNP) | VAF 84/200 reads (42%) | catalogued as COSV101461355; called by muse, mutect2, varscan2
- C12orf77 | n.433A>T | RNA (SNP) | VAF 71/133 reads (53%) | called by muse, mutect2, varscan2
- C9orf163 | n.1162G>C | RNA (SNP) | VAF 41/81 reads (51%) | called by muse, mutect2, varscan2
- DST | c.4296+4918A>C | Intron (SNP) | VAF 26/105 reads (25%) | catalogued as COSV55020214, COSV99758766; called by muse, mutect2, varscan2
- ELOVL5 | c.58+1298C>T | Intron (SNP) | VAF 62/244 reads (25%) | catalogued as COSV100439831; called by muse, mutect2, varscan2
- MIR181B1 | n.81T>C | RNA (SNP) | VAF 25/160 reads (16%) | catalogued as rs1395115094; called by muse, mutect2, varscan2
